Somatic mutation profile of cancer-model specimen HCM-CSHL-0246-C19-85A (3D Organoid; aliquot HCM-CSHL-0246-C19-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0246-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 55.9 years (20,434 days).
Specimen HCM-CSHL-0246-C19-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0e41bba-2f26-4230-9fcd-285fe95d7d29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0246-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0246-C19-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33ead960-15b5-462f-8760-8ae4134c7684

The open-access MAF lists 230 somatic variants for this specimen: 152 protein-altering or splice-affecting, 54 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 54, Nonsense Mutation 10, Intron 8, 5'UTR 8, Frame Shift Del 5, Splice Site 5, RNA 3, 5'Flank 2, 3'UTR 2, Splice Region 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/176 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GRIN2B | c.1672G>A p.V558I | Missense Mutation (SNP) | VAF 342/480 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs1057519004, COSV74206831; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 402/402 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs786204041, CM070297, COSV52711079, COSV52927251, COSV53163944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.1435C>A p.L479M (on ENST00000272895 / NM_173076.3; = p.L161M on NM_015657.3) | Missense Mutation (SNP) | VAF 193/420 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.923); catalogued as COSV99790843; called by muse, mutect2, varscan2
- AC013489.1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51551357; called by muse, mutect2, varscan2
- ALX4 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV61325932; called by muse, mutect2, varscan2
- ARHGAP21 | c.5395C>T p.R1799W | Missense Mutation (SNP) | VAF 179/295 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs768755069, COSV100256513; called by muse, mutect2, varscan2
- ARHGAP22 | c.1944dup p.Y649Ifs*12 | Frame Shift Ins (INS) | VAF 109/501 reads (22%) | catalogued as rs1256821192; called by mutect2, pindel, varscan2
- B3GALT4 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 121/261 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs765360254; called by muse, mutect2, varscan2
- BNC2 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 134/134 reads (100%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.829); catalogued as rs1210859066; called by muse, mutect2, varscan2
- BPIFB2 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs746477434; called by muse, mutect2, varscan2
- BRINP1 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.456); catalogued as rs151087333, COSV56292314; called by muse, mutect2, varscan2
- CELSR1 | c.8960C>T p.P2987L | Missense Mutation (SNP) | VAF 112/223 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); catalogued as rs866441078; called by muse, mutect2, varscan2
- CERK | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs1337514286; called by muse, mutect2, varscan2
- CFAP47 | c.8137G>T p.A2713S | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV66216178; called by muse, mutect2, varscan2
- CHRM4 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 145/289 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1247534212, COSV63127569; called by muse, mutect2, varscan2
- CKMT1B | c.1143G>C p.E381D | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV55852209; called by muse, mutect2, varscan2
- CNTN2 | c.125A>G p.Q42R | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59348607; called by muse, mutect2, varscan2
- CPQ | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs577356141, COSV55138391; called by muse, mutect2, varscan2
- CST2 | c.301T>A p.L101M | Missense Mutation (SNP) | VAF 82/474 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59031360; called by muse, varscan2
- FBN1 | c.4762C>A p.L1588I | Missense Mutation (SNP) | VAF 110/459 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV104413959, COSV57322943; called by muse, mutect2, varscan2
- IDH2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51564478; called by muse, mutect2
- INO80C | c.379+2_379+3del p.X127_splice | Splice Site (DEL) | VAF 112/228 reads (49%) | catalogued as rs1323332387; called by pindel, varscan2
- KCNA3 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs1204573283, COSV100871279; called by muse, mutect2, varscan2
- KHDC3L | c.597C>A p.S199R | Missense Mutation (SNP) | VAF 199/373 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64859440; called by muse, mutect2, varscan2
- KLK6 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 241/531 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs200194649, COSV59565296; called by muse, mutect2, varscan2
- KRTAP4-6 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 44/349 reads (13%) | SIFT deleterious (0.01); catalogued as COSV61982088; called by muse, mutect2, varscan2
- LRP1B | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771071015, COSV67263162; called by muse, mutect2, varscan2
- MAP2 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.838); catalogued as rs747788362; called by muse, mutect2, varscan2
- MYO3A | c.3232A>C p.I1078L | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV56322652; called by muse, mutect2, varscan2
- MYO3A | c.3532G>T p.A1178S | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs767132397; called by muse, mutect2
- NCKAP5L | c.3517G>A p.A1173T | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs766539226; called by muse, mutect2
- NEB | c.4955C>A p.S1652* | Nonsense Mutation (SNP) | VAF 73/193 reads (38%) | catalogued as COSV50805867; called by muse, mutect2, varscan2
- NLRP4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 116/258 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs370421219; called by muse, mutect2, varscan2
- OR2T2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 187/653 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs200389028, COSV100737564; called by muse, mutect2, varscan2
- PAXIP1 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 105/140 reads (75%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.439); catalogued as rs1444898194; called by muse, mutect2, varscan2
- PCDH15 | c.2273A>C p.N758T | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as COSV100213990, COSV57278399; called by muse, mutect2, varscan2
- PDE1B | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs958466168, COSV54490786; called by muse, mutect2, varscan2
- PGM5 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 106/265 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as rs200812025; called by muse, mutect2, varscan2
- PGR | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.742); catalogued as rs749564230, COSV99677589; called by muse, mutect2, varscan2
- PKD1 | c.11135G>A p.R3712Q (on ENST00000262304 / NM_001009944.3; = p.R3711Q on NM_000296.4) | Missense Mutation (SNP) | VAF 199/368 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs144624467; called by muse, mutect2, varscan2
- PRDM9 | c.2512G>T p.G838W | Missense Mutation (SNP) | VAF 116/534 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212449977, COSV57006802; called by muse, mutect2, varscan2
- PRRT4 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs986573221; called by muse, mutect2, varscan2
- PTPRM | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 111/237 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs367853227, COSV59857296; called by muse, mutect2, varscan2
- PTPRQ | c.1609C>G p.H537D (on ENST00000616559; = p.H495D on NM_001145026.2) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99030935; called by muse, mutect2, varscan2
- RECQL | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 67/96 reads (70%) | catalogued as rs376839517, CM155199, COSV59085001; called by muse, mutect2, varscan2
- RHOXF2B | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as rs1157142630; called by mutect2, varscan2
- RNF126 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as rs866241374, COSV52777670; called by muse, mutect2, varscan2
- SEPTIN12 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs369327426; called by muse, mutect2, varscan2
- SGTA | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55593115; called by muse, mutect2
- SLC13A1 | c.932A>C p.N311T | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV52018277; called by muse, mutect2
- SLC16A2 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as rs1375705723; called by muse, mutect2, varscan2
- SLC9A3 | c.2068-5C>T | Splice Region (SNP) | VAF 66/183 reads (36%) | catalogued as rs773708622; called by muse, mutect2, varscan2
- SNTG2 | c.127A>T p.I43F | Missense Mutation (SNP) | VAF 62/402 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1558379741; called by muse, mutect2, varscan2
- SORCS1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs368458074; called by muse, mutect2, varscan2
- SPAG11B | c.62-2A>G p.X21_splice | Splice Site (SNP) | VAF 114/916 reads (12%) | catalogued as rs771318313; called by muse, mutect2, varscan2
- TDRD15 | c.4574T>C p.L1525P | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68267607; called by muse, mutect2, varscan2
- THOP1 | c.751-8G>A | Splice Region (SNP) | VAF 168/200 reads (84%) | catalogued as rs1252019916; called by muse, mutect2, varscan2
- TMEM170B | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 150/349 reads (43%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.982); catalogued as rs1465534575; called by muse, mutect2, varscan2
- TMPRSS9 | c.2222G>A p.S741N (on ENST00000648592; = p.S707N on NM_182973.2) | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1489224087; called by muse, mutect2, varscan2
- TNS1 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1231197789, COSV50702284; called by muse, mutect2
- TRMT9B | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs375051052; called by muse, varscan2
- TRPC4AP | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs893100286, COSV52677477, COSV99328745; called by muse, mutect2, varscan2
- TTYH3 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 97/142 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751600726; called by muse, mutect2, varscan2
- ZNF567 | c.980A>G p.H327R (on ENST00000536254 / NM_001322913.1; = p.H296R on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/420 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767087001; called by muse, mutect2, varscan2
- ZNF765 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 79/435 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201509403; called by muse, mutect2, varscan2
- ABCA13 | c.12659T>A p.L4220Q | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ADGRB3 | c.3169A>C p.K1057Q | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- AEBP1 | c.563G>T p.S188I | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALK | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 122/465 reads (26%) | called by muse, mutect2, varscan2
- ANKRD18B | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 147/256 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- B3GALT4 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, mutect2
- BANF1 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 163/381 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CELF6 | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.07); called by muse, mutect2
- CFAP47 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- COL21A1 | c.1755C>A p.F585L | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX1 | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 101/483 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH5 | c.2438T>A p.L813Q | Missense Mutation (SNP) | VAF 35/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- DOCK3 | c.2930T>A p.L977Q | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- EFL1 | c.2248A>C p.T750P | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- EGFLAM | c.1294C>A p.H432N | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- EIF3A | c.252del p.K84Nfs*11 | Frame Shift Del (DEL) | VAF 36/151 reads (24%) | called by mutect2, pindel, varscan2
- ENTPD2 | c.1285G>A p.A429T (on ENST00000355097 / NM_203468.3; = p.A406T on NM_001246.4) | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, varscan2
- EPG5 | c.3758G>T p.R1253I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EYS | c.4753A>G p.T1585A | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FANCM | c.2123T>G p.V708G | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FGFR1 | c.1190A>G p.Y397C (on ENST00000447712 / NM_023110.3; = p.Y395C on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 183/404 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXF2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- FREM2 | c.8720G>C p.G2907A | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GRIA1 | c.1067A>G p.N356S | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HIVEP3 | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- IGSF21 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 117/218 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ITGAE | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- JKAMP | c.185C>G p.P62R (on ENST00000554271 / NM_001284201.1; = p.P48R on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 211/211 reads (100%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNH3 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 109/176 reads (62%) | called by muse, mutect2, varscan2
- KIDINS220 | c.2974A>G p.I992V | Missense Mutation (SNP) | VAF 113/276 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMP2 | c.918dup p.N307* | Frame Shift Ins (INS) | VAF 20/180 reads (11%) | called by pindel, varscan2
- LAMP2 | c.912T>A p.Y304* | Nonsense Mutation (SNP) | VAF 20/185 reads (11%) | called by muse, varscan2
- LAMP2 | c.911A>T p.Y304F | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.157); called by muse, varscan2
- LNX2 | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- LVRN | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MFAP3 | c.770A>G p.E257G | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MIA3 | c.2826C>G p.Y942* | Nonsense Mutation (SNP) | VAF 47/119 reads (39%) | called by muse, mutect2, varscan2
- MIB2 | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 132/255 reads (52%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- MNAT1 | c.353C>G p.T118S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTSS1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- MUC4 | c.8675G>T p.G2892V | Missense Mutation (SNP) | VAF 177/815 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MYH2 | c.3733T>C p.S1245P | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); called by muse, mutect2
- MYO1A | c.2123A>G p.Y708C | Missense Mutation (SNP) | VAF 137/565 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NAA15 | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- NHSL1 | c.2274del p.N759Mfs*115 | Frame Shift Del (DEL) | VAF 54/139 reads (39%) | called by mutect2, pindel, varscan2
- NOD2 | c.2208G>A p.M736I | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NRF1 | c.1267T>G p.L423V | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OGFRL1 | c.459C>A p.H153Q | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2G6 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2G6 | c.834T>A p.Y278* | Nonsense Mutation (SNP) | VAF 35/167 reads (21%) | called by muse, mutect2, varscan2
- P2RY10 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- PCDHGB5 | c.427A>C p.S143R | Missense Mutation (SNP) | VAF 96/360 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- PCNX1 | c.6388T>G p.C2130G | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PLAA | c.1357G>T p.D453Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PLOD2 | c.339C>A p.C113* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- POTEG | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 172/638 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PROS1 | c.1076T>G p.I359S | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- RHD | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RNF216 | c.1755C>G p.Y585* (on ENST00000425013 / NM_207116.3; = p.Y642* on NM_207111.4) | Nonsense Mutation (SNP) | VAF 28/654 reads (4%) | called by muse, mutect2
- RPAP2 | c.32del p.G11Afs*22 | Frame Shift Del (DEL) | VAF 10/97 reads (10%) | called by mutect2, pindel, varscan2
- SHARPIN | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHPRH | c.1870A>C p.N624H | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2
- SIAH3 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 113/284 reads (40%) | called by muse, mutect2, varscan2
- SKIV2L | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 201/405 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMAD2 | c.1311G>T p.W437C | Missense Mutation (SNP) | VAF 133/133 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMC1B | c.571A>T p.N191Y | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SORCS1 | c.2344A>G p.R782G | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.165); called by muse, mutect2
- SPAG11A | c.62-2A>G p.X21_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | called by mutect2, varscan2
- SPAG11A | c.62-1G>T p.X21_splice | Splice Site (SNP) | VAF 3/17 reads (18%) | called by mutect2, varscan2
- SPAG11B | c.62-1G>T p.X21_splice | Splice Site (SNP) | VAF 114/919 reads (12%) | called by muse, mutect2, varscan2
- SSTR1 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- SSX2IP | c.399T>G p.H133Q | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- STK39 | c.960A>T p.K320N | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF1L | c.5350A>C p.N1784H | Missense Mutation (SNP) | VAF 122/394 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAF7 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- TG | c.2348A>G p.E783G | Missense Mutation (SNP) | VAF 125/383 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- THOC3 | c.309C>G p.D103E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- TRIM61 | c.276A>C p.E92D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by mutect2, varscan2
- TTN | c.81216_81229del p.S27072Rfs*3 (on ENST00000591111; = p.S19648Rfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 26/151 reads (17%) | called by mutect2, pindel, varscan2
- UBR2 | c.4624C>T p.H1542Y | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- UNC50 | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 274/475 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- WNT2 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- YTHDC2 | c.1359+1del | Frame Shift Del (DEL) | VAF 98/442 reads (22%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.4343A>G p.D1448G (on ENST00000242848 / NM_001330565.2; = p.D1449G on NM_015070.6) | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ZNF329 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- ZNF407 | c.859_876del p.Q287_K292del | In Frame Del (DEL) | VAF 46/55 reads (84%) | called by mutect2, pindel, varscan2
- ADCYAP1R1 | c.606C>T p.S202= | Silent (SNP) | VAF 20/208 reads (10%) | catalogued as rs768098970, COSV58441923; called by muse, mutect2
- ANK3 | c.12111G>A p.S4037= | Silent (SNP) | VAF 98/290 reads (34%) | catalogued as rs557280144, COSV55090361; called by muse, mutect2, varscan2
- ANKRD34A | c.303C>T p.G101= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as rs1173022118; called by muse, mutect2, varscan2
- ANP32A | c.309C>A p.L103= | Silent (SNP) | VAF 30/432 reads (7%) | called by muse, mutect2
- APOB | c.2118G>A p.G706= | Silent (SNP) | VAF 99/375 reads (26%) | catalogued as rs1159654255, COSV51952270; called by muse, mutect2, varscan2
- BCL7C | c.654G>A p.P218= | Silent (SNP) | VAF 26/218 reads (12%) | catalogued as rs748583061, COSV66692263; called by muse, mutect2, varscan2
- BPNT1 | c.705T>G p.A235= | Silent (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- CC2D1A | c.588C>T p.A196= | Silent (SNP) | VAF 22/304 reads (7%) | called by muse, mutect2
- COL11A2 | c.3237G>T p.V1079= (on ENST00000341947 / NM_080680.3; = p.V972= on NM_080679.2) | Silent (SNP) | VAF 62/726 reads (9%) | called by muse, mutect2
- COL22A1 | c.4491C>A p.G1497= | Silent (SNP) | VAF 65/134 reads (49%) | called by muse, mutect2, varscan2
- CSNK1G2 | c.741C>T p.R247= | Silent (SNP) | VAF 77/151 reads (51%) | catalogued as rs373599985; called by muse, mutect2, varscan2
- CTNNA1 | c.99T>C p.V33= | Silent (SNP) | VAF 7/201 reads (3%) | called by muse, mutect2
- CYP2U1 | c.354C>T p.F118= | Silent (SNP) | VAF 150/390 reads (38%) | called by muse, mutect2, varscan2
- CYRIA | c.582G>A p.T194= | Silent (SNP) | VAF 110/316 reads (35%) | catalogued as rs753862688, COSV62866917; called by muse, mutect2, varscan2
- DDC | c.1410G>T p.L470= | Silent (SNP) | VAF 323/694 reads (47%) | called by muse, mutect2, varscan2
- DDX1 | c.1722A>T p.V574= | Silent (SNP) | VAF 12/306 reads (4%) | catalogued as COSV51841082; called by muse, mutect2
- ERICH6B | c.1371A>G p.L457= | Silent (SNP) | VAF 51/127 reads (40%) | called by muse, mutect2, varscan2
- FLG | c.4365C>T p.H1455= | Silent (SNP) | VAF 158/338 reads (47%) | catalogued as rs142950612; called by muse, mutect2, varscan2
- GBX2 | c.444G>A p.A148= | Silent (SNP) | VAF 52/600 reads (9%) | catalogued as rs1386615343; called by muse, mutect2
- GFPT2 | c.912T>C p.S304= | Silent (SNP) | VAF 70/278 reads (25%) | called by muse, mutect2, varscan2
- GLI3 | c.3066G>A p.P1022= | Silent (SNP) | VAF 270/398 reads (68%) | catalogued as rs1206623585, COSV67885002; called by muse, mutect2, varscan2
- HRH3 | c.990G>A p.S330= | Silent (SNP) | VAF 81/120 reads (68%) | catalogued as rs199993900; called by muse, mutect2, varscan2
- HSPA12B | c.1275C>T p.N425= | Silent (SNP) | VAF 75/166 reads (45%) | catalogued as rs776009719; called by muse, mutect2, varscan2
- HTR6 | c.430C>T p.L144= | Silent (SNP) | VAF 171/383 reads (45%) | called by muse, mutect2, varscan2
- IQGAP2 | c.957C>T p.P319= | Silent (SNP) | VAF 69/262 reads (26%) | catalogued as rs781281584, COSV99169248; called by muse, mutect2, varscan2
- KCNG2 | c.186C>T p.Y62= | Silent (SNP) | VAF 53/53 reads (100%) | called by muse, mutect2, varscan2
- KLF4 | c.1080C>A p.V360= | Silent (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
- LYAR | c.519A>G p.K173= | Silent (SNP) | VAF 234/235 reads (100%) | called by muse, mutect2, varscan2
- MAB21L1 | c.585G>A p.P195= | Silent (SNP) | VAF 83/169 reads (49%) | catalogued as rs368588802; called by muse, mutect2, varscan2
- MAGEB6B | c.945G>A p.G315= | Silent (SNP) | VAF 59/147 reads (40%) | called by muse, mutect2, varscan2
- MAGEL2 | c.534G>T p.P178= | Silent (SNP) | VAF 84/128 reads (66%) | called by muse, mutect2, varscan2
- MFF | c.606G>A p.S202= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs555978161, COSV58825984; called by muse, mutect2, varscan2
- MTERF3 | c.993C>T p.T331= | Silent (SNP) | VAF 87/87 reads (100%) | catalogued as rs758644998, COSV54635141; called by muse, mutect2, varscan2
- NLRP5 | c.1776C>A p.A592= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as COSV66763646; called by muse, mutect2, varscan2
- NT5DC4 | c.1002T>A p.T334= | Silent (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- OR11G2 | c.882G>T p.L294= | Silent (SNP) | VAF 72/161 reads (45%) | called by muse, mutect2, varscan2
- OSTF1 | c.324T>C p.T108= | Silent (SNP) | VAF 46/160 reads (29%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1335G>T p.V445= | Silent (SNP) | VAF 148/481 reads (31%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1935C>T p.A645= | Silent (SNP) | VAF 296/408 reads (73%) | called by muse, mutect2, varscan2
- PIWIL1 | c.144C>T p.G48= | Silent (SNP) | VAF 76/216 reads (35%) | called by muse, mutect2, varscan2
- PLEKHF1 | c.810G>A p.S270= | Silent (SNP) | VAF 100/166 reads (60%) | catalogued as rs373551601; called by mutect2, varscan2
- PRDM9 | c.363G>A p.K121= | Silent (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- PTCH2 | c.1395A>T p.G465= | Silent (SNP) | VAF 46/484 reads (10%) | called by muse, mutect2
- SERPINA6 | c.78C>T p.N26= | Silent (SNP) | VAF 229/229 reads (100%) | catalogued as rs758471605; called by muse, mutect2, varscan2
- SGSM1 | c.1068C>T p.G356= | Silent (SNP) | VAF 97/185 reads (52%) | catalogued as rs371807192; called by muse, mutect2, varscan2
- SH3BP4 | c.249C>T p.Y83= | Silent (SNP) | VAF 93/155 reads (60%) | catalogued as rs778110762; called by muse, mutect2, varscan2
- SNRNP200 | c.2490C>T p.G830= | Silent (SNP) | VAF 193/779 reads (25%) | called by muse, mutect2, varscan2
- SPATA31A6 | c.2265G>A p.Q755= | Silent (SNP) | VAF 91/394 reads (23%) | catalogued as rs1458571466; called by muse, mutect2, varscan2
- SSH1 | c.1323T>A p.S441= | Silent (SNP) | VAF 115/461 reads (25%) | called by muse, mutect2, varscan2
- TAT | c.42C>A p.L14= | Silent (SNP) | VAF 62/414 reads (15%) | catalogued as COSV63532619; called by muse, mutect2, varscan2
- TENM2 | c.1455C>T p.L485= (on ENST00000518659 / NM_001122679.2; = p.L253= on NM_001080428.3) | Silent (SNP) | VAF 69/342 reads (20%) | catalogued as rs773074265, COSV69146539; called by muse, mutect2, varscan2
- TRAPPC9 | c.300C>T p.H100= | Silent (SNP) | VAF 126/248 reads (51%) | catalogued as rs200067455; called by muse, mutect2, varscan2
- ZNF20 | c.1164G>A p.T388= | Silent (SNP) | VAF 70/204 reads (34%) | catalogued as rs745920069, COSV61998713; called by muse, mutect2, varscan2
- ZNF550 | c.420G>C p.V140= | Silent (SNP) | VAF 267/495 reads (54%) | called by muse, mutect2, varscan2
- AC073348.1 | n.167dup | RNA (INS) | VAF 108/178 reads (61%) | catalogued as rs761017316; called by mutect2, varscan2
- AC244517.10 | c.36-10273C>T | Intron (SNP) | VAF 57/237 reads (24%) | catalogued as rs1554290441; called by muse, mutect2, varscan2
- AC244517.10 | c.36-9305A>C | Intron (SNP) | VAF 51/648 reads (8%) | called by muse, mutect2
- CHRND | c.*768C>A | 3'UTR (SNP) | VAF 26/425 reads (6%) | called by muse, mutect2
- DSCC1 | c.*25A>T | 3'UTR (SNP) | VAF 15/202 reads (7%) | called by muse, mutect2
- FGF22 | c.214+1098C>T | Intron (SNP) | VAF 22/246 reads (9%) | catalogued as rs116901967, COSV99293865; called by muse, mutect2
- FSHR | c.374+2605T>C | Intron (SNP) | VAF 15/277 reads (5%) | called by muse, mutect2
- GCNT2P1 | n.728G>A | RNA (SNP) | VAF 45/89 reads (51%) | catalogued as rs1434883962; called by muse, mutect2, varscan2
- GOLGA8K | c.48+101T>G | Intron (SNP) | VAF 205/207 reads (99%) | called by muse, mutect2, varscan2
- GPR141 | chr7:37740393 T>A | 5'Flank (SNP) | VAF 39/53 reads (74%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.-20A>C | 5'UTR (SNP) | VAF 167/446 reads (37%) | catalogued as rs780015776; called by muse, mutect2, varscan2
- LIMK1 | c.-32_-28del | 5'UTR (DEL) | VAF 19/31 reads (61%) | called by mutect2, pindel, varscan2
- MFSD4B | c.27+2595C>A | Intron (SNP) | VAF 93/229 reads (41%) | catalogued as rs770452076; called by muse, mutect2, varscan2
- NRXN1 | c.3365-110009C>T | Intron (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- OFCC1 | n.2004C>A | RNA (SNP) | VAF 24/234 reads (10%) | called by muse, mutect2
- PRKRIP1 | c.-652G>T | 5'UTR (SNP) | VAF 157/557 reads (28%) | catalogued as COSV101461530; called by muse, mutect2, varscan2
- PTMA | chr2:231707778 G>T | 5'Flank (SNP) | VAF 87/390 reads (22%) | called by muse, mutect2, varscan2
- RIPOR2 | c.-105G>A | 5'UTR (SNP) | VAF 36/75 reads (48%) | catalogued as COSV73375358; called by muse, mutect2, varscan2
- RPL37AP1 | chr20:44462219 C>T | 3'Flank (SNP) | VAF 61/145 reads (42%) | called by muse, mutect2, varscan2
- SNRPC | c.9-10del | Intron (DEL) | VAF 49/188 reads (26%) | called by mutect2, pindel, varscan2
- STARD8 | c.-162C>A | 5'UTR (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- TPCN1 | c.-3A>C | 5'UTR (SNP) | VAF 114/426 reads (27%) | called by muse, mutect2, varscan2
- VAT1L | c.-6A>T | 5'UTR (SNP) | VAF 23/197 reads (12%) | called by muse, mutect2, varscan2
- ZNF517 | c.-22T>C | 5'UTR (SNP) | VAF 10/151 reads (7%) | catalogued as rs1363817119; called by muse, mutect2
